CCDI case PBCKRS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/098d4716-3de6-47ba-b019-0cf570372fe1

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,276 days).

Biospecimens (3 samples)
- Sample 0DUHG8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUHH0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUHI1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
